Somatic mutation profile of tumor specimen TCGA-BR-8484-01A (aliquot TCGA-BR-8484-01A-11D-2394-08) from TCGA case TCGA-BR-8484, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.8 years (22,583 days).
Specimen TCGA-BR-8484-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb0fc727-21a3-4a68-bfbd-9e6e94334fe6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8484-10A (Blood Derived Normal), aliquot TCGA-BR-8484-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93b39cef-5d47-412e-b2c2-b283ca687a71

The open-access MAF lists 88 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 56, Silent 23, Splice Region 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACVR2A | c.20T>A p.L7* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as COSV54023714; called by muse, mutect2, varscan2
- ADARB1 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62344786; called by muse, mutect2, varscan2
- ADGRB3 | c.2535T>G p.D845E | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.339); catalogued as COSV53238614, COSV53247372; called by muse, mutect2, varscan2
- ADGRL2 | c.4027G>C p.V1343L (on ENST00000370717 / NM_001366005.1; = p.V1287L on NM_012302.4) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.145); catalogued as COSV54670735; called by muse, mutect2
- AKAP9 | c.10600C>A p.H3534N (on ENST00000359028; = p.H3510N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/867 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.182); catalogued as COSV62348176; called by muse, mutect2
- AL592490.1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1270126658, COSV69426590; called by muse, mutect2, varscan2
- ATP1A4 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs147875149; called by muse, mutect2, varscan2
- C1orf174 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs776552583, COSV64365894; called by muse, mutect2, varscan2
- CACNA1I | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV60810314; called by muse, mutect2, varscan2
- CAMSAP1 | c.2569C>T p.Q857* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV56723459; called by muse, mutect2, varscan2
- CASP9 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs754180617, COSV61601602; called by muse, mutect2, varscan2
- CCDC178 | c.465G>C p.K155N | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV55776736; called by muse, mutect2, varscan2
- COL4A1 | c.2794C>T p.P932S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65426930; called by muse, mutect2
- CWH43 | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56939559; called by muse, mutect2, varscan2
- CYFIP2 | c.2154G>A p.E718= (on ENST00000616178 / NM_001291722.2; = p.E693= on NM_014376.4) | Splice Region (SNP) | VAF 13/99 reads (13%) | catalogued as COSV59040520; called by muse, mutect2, varscan2
- DDX3X | c.1057G>T p.D353Y (on ENST00000399959; = p.D354Y on NM_001356.5) | Missense Mutation (SNP) | VAF 47/83 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67863073, COSV67863895, COSV67863993; called by muse, mutect2, varscan2
- DPP10 | c.1419A>C p.E473D | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV59683597; called by muse, mutect2
- EDA2R | c.12A>C p.Q4H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53631648; called by muse, mutect2
- ELAVL4 | c.464A>G p.Y155C | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV63916278; called by muse, mutect2
- ERI3 | c.933C>T p.D311= | Splice Region (SNP) | VAF 6/44 reads (14%) | catalogued as rs773605425, COSV59999922; called by muse, varscan2
- FBN1 | c.3017A>G p.E1006G | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV57318952; called by muse, mutect2, varscan2
- FBXO43 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs770938371, COSV71053928; called by muse, mutect2, varscan2
- FCRL3 | c.53-2A>C p.X18_splice | Splice Site (SNP) | VAF 6/69 reads (9%) | catalogued as COSV63842070; called by muse, mutect2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- HK3 | c.2728G>T p.V910F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs756312063, COSV52840849; called by muse, mutect2, varscan2
- IFNA10 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 144/405 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as rs762249251, COSV53331273; called by muse, mutect2, varscan2
- IL18 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV54781693; called by muse, mutect2, varscan2
- KCND2 | c.1166T>C p.I389T | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV58583025; called by muse, mutect2, varscan2
- KIF24 | c.1984C>T p.P662S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV61455778; called by muse, mutect2, varscan2
- LAMA4 | c.300C>T p.H100= | Splice Region (SNP) | VAF 7/82 reads (9%) | catalogued as rs1554354611, COSV57898341; called by muse, mutect2
- LCE2A | c.298C>T p.H100Y | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.065); catalogued as COSV64226871; called by muse, mutect2, varscan2
- LPCAT2 | c.1283A>T p.N428I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50896204; called by muse, mutect2, varscan2
- LRIT1 | c.1659G>C p.Q553H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV64512016, COSV64512837; called by muse, mutect2, varscan2
- MUC16 | c.38930C>T p.S12977F | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.979); catalogued as rs796613110, COSV67471175; called by muse, mutect2
- NEXMIF | c.3297A>T p.Q1099H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV50036906; called by muse, mutect2, varscan2
- ODF3 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1050558695, COSV57292797; called by muse, mutect2, varscan2
- OR10X1 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63767472; called by muse, mutect2, varscan2
- OR2T3 | c.937A>G p.R313G | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV62083057, COSV62083737; called by muse, mutect2
- OR6N2 | c.444T>A p.C148* | Nonsense Mutation (SNP) | VAF 10/95 reads (11%) | catalogued as COSV59411737; called by muse, mutect2, varscan2
- OR6V1 | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs200139748; called by muse, mutect2
- OR8D2 | c.614T>G p.V205G | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV62488572; called by muse, mutect2
- PCDH15 | c.2961A>T p.R987S | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.232); catalogued as COSV57323897; called by muse, mutect2
- PCDH17 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1365330657, COSV64974886; called by muse, mutect2
- PNLIPRP2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782045216, COSV53944274; called by muse, mutect2, varscan2
- PSG11 | c.607T>C p.F203L | Missense Mutation (SNP) | VAF 48/516 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as rs1177783014, COSV60453702; called by muse, mutect2
- RAB6D | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774998798, COSV72151612; called by muse, mutect2
- ROS1 | c.5000C>T p.P1667L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.448); catalogued as rs866472077, COSV63856218; called by muse, mutect2
- SAMD9L | c.4591G>A p.G1531S | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as COSV59081306, COSV59082168; called by muse, mutect2
- SCLT1 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.453); catalogued as rs1326499482, COSV55406984; called by muse, mutect2
- SEMA6D | c.724G>A p.V242I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV60378369; called by muse, mutect2, varscan2
- SHC3 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs372149510; called by muse, mutect2, varscan2
- SHH | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM041835, CM095861, COSV51919042; called by muse, mutect2, varscan2
- SLC17A6 | c.978T>G p.F326L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV54137128, COSV54138444; called by muse, mutect2, varscan2
- STOX1 | c.1913C>T p.P638L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779394146, COSV53815324; called by muse, mutect2, varscan2
- SULF2 | c.2494+1G>A p.X832_splice | Splice Site (SNP) | VAF 15/215 reads (7%) | catalogued as COSV59069389; called by muse, mutect2
- TSHZ2 | c.931A>C p.T311P | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.773); catalogued as COSV61589163; called by muse, mutect2
- WNT10A | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV51462699; called by muse, mutect2, varscan2
- ASCC3 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- CYB5A | c.238A>C p.I80L | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- OR9G4 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRAMEF15 | c.444del p.L149* | Frame Shift Del (DEL) | VAF 89/917 reads (10%) | called by mutect2, pindel, varscan2
- TGFBR3 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- TRAV14DV4 | c.253T>C p.S85P | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- UBASH3B | c.603A>C p.E201D | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AKAP6 | c.2460G>A p.E820= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs1566585175, COSV55216158; called by muse, mutect2, varscan2
- BRINP3 | c.1809A>G p.L603= | Silent (SNP) | VAF 32/358 reads (9%) | catalogued as rs1405520238, COSV66526832; called by muse, mutect2
- CDH23 | c.234T>C p.F78= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99822186; called by muse, mutect2, varscan2
- CFTR | c.1800G>A p.R600= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as CD067855, COSV50059558; called by muse, mutect2
- CHRM2 | c.327C>G p.A109= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV57774079; called by muse, mutect2, varscan2
- CLECL1 | c.243A>T p.G81= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV59931464; called by muse, mutect2, varscan2
- DNAH10 | c.7944G>A p.S2648= (on ENST00000409039; = p.S2587= on NM_207437.3) | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs756969762, COSV68994974; called by muse, mutect2, varscan2
- GPR149 | c.948G>A p.A316= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as rs199866600; called by muse, mutect2
- GRID1 | c.438C>T p.P146= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as rs764843634, COSV60012496; called by muse, mutect2, varscan2
- HAS1 | c.627G>T p.A209= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55787887; called by muse, mutect2
- HTR1A | c.1230G>A p.A410= | Silent (SNP) | VAF 19/316 reads (6%) | catalogued as rs757637361, COSV60501151; called by muse, mutect2
- HUWE1 | c.360A>G p.T120= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs1557034872, COSV53348233; called by muse, varscan2
- KCNH2 | c.972C>T p.L324= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs146297032; called by muse, mutect2, varscan2
- LAMC1 | c.3312G>A p.Q1104= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV51135526, COSV51146254; called by muse, mutect2, varscan2
- LAMC3 | c.1995G>A p.P665= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs747496537, COSV63092152; called by muse, mutect2, varscan2
- MAP2 | c.4086T>C p.S1362= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as COSV52293609; called by muse, mutect2
- PHKG2 | c.1008G>A p.L336= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV60312318; called by muse, mutect2, varscan2
- PTCD3 | c.2043C>T p.S681= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as rs1355104042, COSV54480632; called by muse, mutect2
- SDK1 | c.681A>G p.R227= | Silent (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- STAG3 | c.3381A>G p.E1127= | Silent (SNP) | VAF 11/80 reads (14%) | catalogued as COSV57931135; called by muse, mutect2, varscan2
- SULF2 | c.531C>T p.N177= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1212802155, COSV63413673; called by muse, mutect2, varscan2
- USP38 | c.369C>T p.L123= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV61026131; called by muse, mutect2, varscan2
- XKR4 | c.822A>T p.I274= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV59319271; called by muse, mutect2, varscan2
